Somatic mutation profile of tumor specimen C3L-03630-02 (aliquot CPT0198910008) from CPTAC case C3L-03630, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 78.5 years (28,674 days).
Specimen C3L-03630-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75683401-017b-44ee-b026-8078dc1c670c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03630-31 (Blood Derived Normal), aliquot CPT0198940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fce3e381-a089-412f-aa07-8976a6ab1974

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 7, Intron 3, Nonsense Mutation 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 85/575 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 103/620 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 28/207 reads (14%) | catalogued as rs775795770; called by muse, mutect2, varscan2
- ADAMTS19 | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 49/405 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1045960086; called by muse, mutect2, varscan2
- ANKRD30BL | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs751958828; called by muse, mutect2, varscan2
- C1orf109 | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs758937443; called by muse, mutect2, varscan2
- CCDC25 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); catalogued as COSV62958969; called by muse, mutect2
- CDK5RAP2 | c.915A>C p.E305D | Missense Mutation (SNP) | VAF 63/619 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62572192; called by muse, mutect2, varscan2
- CDKN2A | c.150+1G>C p.X50_splice | Splice Site (SNP) | VAF 74/456 reads (16%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2, varscan2
- CEP170B | c.2362A>G p.R788G (on ENST00000453495; = p.R717G on NM_015005.3) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV69025456; called by muse, mutect2
- CRYGC | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 65/523 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as rs539234728, COSV52205791; called by muse, mutect2, varscan2
- ERICH3 | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs779101589, COSV58605623; called by muse, mutect2, varscan2
- FAM120A | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 109/706 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs764432382; called by muse, mutect2, varscan2
- HNRNPDL | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 54/636 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV99040410; called by muse, mutect2
- IQCB1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1272185942; called by muse, mutect2
- IQSEC3 | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs747026524, COSV58290439; called by muse, mutect2, varscan2
- LIMK2 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 47/550 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs769771373; called by muse, mutect2
- MMP17 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 48/698 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs779153151, COSV62179778; called by muse, mutect2
- MORC1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 57/494 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV99225584; called by muse, varscan2
- NECAB2 | c.672C>A p.N224K | Missense Mutation (SNP) | VAF 81/576 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs766121001; called by mutect2, varscan2
- PLEC | c.13597G>A p.G4533S (on ENST00000322810 / NM_201380.4; = p.G4423S on NM_000445.5) | Missense Mutation (SNP) | VAF 94/591 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759155242; called by muse, mutect2, varscan2
- PROKR1 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 97/633 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748147832, COSV100375851; called by muse, mutect2, varscan2
- RAPSN | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 74/649 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs781724566, COSV54084160, COSV54085719; called by muse, mutect2, varscan2
- SHQ1 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 100/730 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV57764869; called by muse, mutect2, varscan2
- TBX2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs770492149; called by muse, mutect2, varscan2
- TUBGCP2 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as rs759006952; called by muse, mutect2
- ADGRB3 | c.2863T>A p.S955T | Missense Mutation (SNP) | VAF 23/336 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- AHI1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 85/466 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP24 | c.733-1G>A p.X245_splice (on ENST00000395184 / NM_001025616.3; = p.X152_splice on NM_031305.3) | Splice Site (SNP) | VAF 42/648 reads (6%) | called by muse, mutect2
- C6orf132 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- C6orf132 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 141/507 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C6orf132 | c.2003G>C p.G668A | Missense Mutation (SNP) | VAF 619/2440 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CDH20 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DVL3 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 95/739 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EEF1AKMT2 | c.806C>G p.S269* | Nonsense Mutation (SNP) | VAF 25/202 reads (12%) | called by muse, mutect2, varscan2
- KIFC1 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- MRPS5 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MYO10 | c.2981A>G p.D994G | Missense Mutation (SNP) | VAF 104/672 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFKBIL1 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 134/429 reads (31%) | called by muse, mutect2, varscan2
- NOL6 | c.590A>C p.Q197P | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- NRBP2 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 65/508 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.6608T>G p.F2203C | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TARS3 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNNC2 | c.377A>G p.H126R | Missense Mutation (SNP) | VAF 79/584 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WDR17 | c.1232C>G p.T411R | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFHX4 | c.10051A>C p.K3351Q | Missense Mutation (SNP) | VAF 75/664 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CDH4 | c.1905G>A p.A635= | Silent (SNP) | VAF 164/1149 reads (14%) | catalogued as rs936184978; called by muse, mutect2, varscan2
- FADS1 | c.1341G>A p.T447= | Silent (SNP) | VAF 45/330 reads (14%) | catalogued as rs115713429; called by muse, mutect2, varscan2
- IGLV1-36 | c.201C>A p.L67= | Silent (SNP) | VAF 116/762 reads (15%) | called by muse, mutect2, varscan2
- PNO1 | c.723T>C p.I241= | Silent (SNP) | VAF 27/233 reads (12%) | catalogued as rs1469855360, COSV52249329; called by muse, mutect2, varscan2
- PTPRJ | c.1164C>A p.V388= | Silent (SNP) | VAF 34/315 reads (11%) | catalogued as rs762925560; called by muse, mutect2, varscan2
- SMC6 | c.1185T>A p.T395= | Silent (SNP) | VAF 27/185 reads (15%) | called by muse, mutect2, varscan2
- THAP11 | c.771C>T p.L257= | Silent (SNP) | VAF 45/336 reads (13%) | catalogued as rs774473286; called by muse, mutect2, varscan2
- RCC1 | c.-261-622T>G | Intron (SNP) | VAF 33/727 reads (5%) | called by muse, mutect2
- TENM4 | c.-321+38429T>A | Intron (SNP) | VAF 23/165 reads (14%) | called by muse, mutect2, varscan2
- TRIOBP | c.6324+289C>T | Intron (SNP) | VAF 126/893 reads (14%) | called by muse, mutect2, varscan2
